Somatic mutation profile of tumor specimen MMRF_1371_1_BM_CD138pos (aliquot MMRF_1371_1_BM_CD138pos_T1_KAS5U_L00689) from MMRF case MMRF_1371, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,355 days).
Specimen MMRF_1371_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faba417d-90a8-43fe-9ac6-465d1344bf7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1371_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1371_1_PB_Whole_C2_KAS5U_L00697; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/491b5d1a-073e-49e7-835d-18c3b127369f

The open-access MAF lists 88 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 26, Silent 12, Intron 5, 5'UTR 3, 5'Flank 3, RNA 2, Nonsense Mutation 2, 3'Flank 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 66/156 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6326G>A p.R2109H (on ENST00000614293; = p.R2079H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs370859557; called by muse, mutect2, varscan2
- ADGRB1 | c.3958G>A p.V1320I | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs745792187, COSV60095999; called by muse, mutect2, varscan2
- DNAH9 | c.8692G>A p.D2898N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52332075; called by muse, mutect2, varscan2
- H2BC21 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV58611725; called by muse, mutect2, varscan2
- IGLV3-1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs145382269; called by muse, varscan2
- IGLV3-1 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs542922165; called by muse, varscan2
- IGLV3-1 | c.295A>T p.M99L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs61731681; called by muse, varscan2
- IGLV3-1 | c.300T>G p.D100E | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554611867; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, varscan2
- IGLV4-3 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as rs576246152; called by muse, mutect2, varscan2
- IGSF10 | c.270C>A p.S90R | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774315574; called by muse, mutect2, varscan2
- MCHR2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs1015907823, COSV56002006, COSV99912673; called by muse, mutect2, varscan2
- PRRG1 | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 51/52 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV66157386; called by muse, mutect2, varscan2
- RNF212 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV67113477; called by muse, mutect2, varscan2
- TNK1 | c.1340G>A p.G447D (on ENST00000576812 / NM_001251902.2; = p.G442D on NM_003985.5) | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs755597216; called by muse, mutect2, varscan2
- TRPC7 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.785); catalogued as COSV100725356, COSV61465568; called by muse, mutect2, varscan2
- ZFHX3 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764820053, COSV99213393; called by muse, mutect2, varscan2
- CADM2 | c.510A>T p.K170N (on ENST00000407528 / NM_001167674.2; = p.K172N on NM_153184.4) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CNTNAP5 | c.1901A>G p.H634R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ECH1 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO38 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO7 | c.1115G>A p.W372* | Nonsense Mutation (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.234A>C p.K78N | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- IGKV2D-29 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- KCNH7 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- KREMEN1 | c.914C>A p.S305Y (on ENST00000407188; = p.S307Y on NM_032045.5) | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCOR2 | c.5119G>A p.A1707T | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAD54L2 | c.2351-2A>C p.X784_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- RIPK1 | c.1729+5G>A | Splice Region (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- SPAG4 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TTLL6 | c.326T>C p.L109S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UCKL1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSIG1 | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN18 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPAMD8 | c.4173G>C p.G1391= (on ENST00000651564; = p.G1344= on NM_015692.5) | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CYP17A1 | c.1524C>T p.T508= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs145067399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIAPH2 | c.1113T>C p.D371= | Silent (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- DMAP1 | c.381C>T p.A127= | Silent (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- EFHD1 | c.309C>T p.D103= | Silent (SNP) | VAF 58/124 reads (47%) | catalogued as rs983959718, COSV51132622; called by muse, mutect2, varscan2
- ERP44 | c.99T>C p.S33= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- GRIA2 | c.111C>A p.A37= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs754868379; called by muse, mutect2, varscan2
- HAO1 | c.915T>C p.A305= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- IGHG1 | c.30C>G p.P10= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- L2HGDH | c.78G>A p.A26= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs778118435; called by muse, mutect2, varscan2
- NOL12 | c.291G>A p.Q97= | Silent (SNP) | VAF 71/135 reads (53%) | called by muse, mutect2, varscan2
- SULT2B1 | c.507G>A p.P169= (on ENST00000201586 / NM_177973.2; = p.P154= on NM_004605.2) | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as rs761051297, COSV52374835; called by muse, mutect2, varscan2
- AC016596.1 | chr5:56003038 G>A | 5'Flank (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- AC017076.1 | n.122T>A | RNA (SNP) | VAF 5/45 reads (11%) | catalogued as rs1265951746; called by muse, varscan2
- C20orf85 | c.*287dup | 3'UTR (INS) | VAF 26/46 reads (57%) | catalogued as rs797013982; called by mutect2, varscan2
- C9orf131 | c.*11G>A | 3'UTR (SNP) | VAF 127/195 reads (65%) | called by muse, mutect2, varscan2
- CHP2 | c.67+59C>T | Intron (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- CLDN12 | c.*2028A>C | 3'UTR (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- DCST2 | c.-74C>T | 5'UTR (SNP) | VAF 45/88 reads (51%) | catalogued as rs114756009; called by muse, mutect2, varscan2
- DHRS3 | c.-216T>G | 5'UTR (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- FFAR4 | c.*950G>A | 3'UTR (SNP) | VAF 33/72 reads (46%) | catalogued as COSV65160334; called by muse, mutect2, varscan2
- GP5 | c.*218G>A | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- HIPK3 | c.*2027G>A | 3'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs541620743; called by muse, mutect2, varscan2
- HMGN3 | chr6:79234767 G>A | 5'Flank (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- HOXA3 | chr7:27106635 C>A | 3'Flank (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- KLHDC7A | c.*2239G>A | 3'UTR (SNP) | VAF 20/61 reads (33%) | catalogued as rs906874521; called by muse, mutect2, varscan2
- KRT80 | c.*1535G>C | 3'UTR (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- LINC02694 | n.854_856del | RNA (DEL) | VAF 41/105 reads (39%) | called by mutect2, pindel, varscan2
- MACROH2A1 | chr5:135334288 A>G | 3'Flank (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- MALT1 | c.*2975G>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- MISP3 | c.*104T>C | 3'UTR (SNP) | VAF 53/161 reads (33%) | catalogued as rs1338904047; called by muse, mutect2, varscan2
- MPPED2 | c.*145del | 3'UTR (DEL) | VAF 39/96 reads (41%) | called by mutect2, pindel, varscan2
- NSG2 | c.*1057G>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- PABPC1L2B | c.*1035C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | catalogued as rs1240165901; called by muse, mutect2
- PEX12 | c.-515C>T | 5'UTR (SNP) | VAF 7/141 reads (5%) | catalogued as rs1481134436; called by muse, mutect2
- PLEKHA5 | c.1846-13995C>A | Intron (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- POGK | c.*2785G>T | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- POU1F1 | c.*475C>T | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- PTCD1 | c.*256A>C | 3'UTR (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- RBM11 | c.*727G>A | 3'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- RPL27A | c.*2539G>A | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- SHANK2 | c.*891G>T | 3'UTR (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- SHOX2 | c.*1353G>A | 3'UTR (SNP) | VAF 30/85 reads (35%) | catalogued as rs1559893216; called by muse, mutect2, varscan2
- SOAT1 | c.*1656A>G | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- SORL1 | c.*1817A>T | 3'UTR (SNP) | VAF 8/134 reads (6%) | catalogued as rs897421060; called by muse, mutect2
- SOX11 | c.*5884A>C | 3'UTR (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- SRSF7 | c.386+192T>C | Intron (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- TGFB2 | c.*159G>A | 3'UTR (SNP) | VAF 26/48 reads (54%) | catalogued as rs1346786037; called by muse, mutect2, varscan2
- TPD52L1 | c.487-92T>C | Intron (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- TSPAN11 | c.*2802T>C | 3'UTR (SNP) | VAF 44/68 reads (65%) | catalogued as rs1480908199; called by muse, mutect2, varscan2
- VMO1 | chr17:4786430 G>A | 5'Flank (SNP) | VAF 17/42 reads (40%) | catalogued as rs920904152; called by mutect2, varscan2
- ZNF621 | c.*4536T>C | 3'UTR (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2, varscan2
- ZSCAN30 | c.554-3785T>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
